Surgical pathology report (de-identified scan), TCGA case TCGA-GR-A4D9, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site University of Nebraska Medical Center (UNMC), specimen TCGA-GR-A4D9-01B (Primary Tumor).

[page 1 of 6]
Department of Pathology and Microbiology

Name: [Redacted]
Hosp No: [Redacted] Acct No: [Redacted]
DOB: [Redacted] Age: [Redacted]
Sex: [Redacted] SSN: [Redacted]
Loc: [Redacted] Room: [Redacted]

Accession No: [Redacted]
Date Taken: [Redacted]
Date Received: [Redacted]
Submitted by: [Redacted]
Client: [Redacted]

Surgical Pathology

Final Diagnosis:

LBFT NECK LYMPH NODE, EXCISION: LYMPH NODE WITH DIFFUSE LARGE B-CELL
LYMPHOMA, NONCLEAVED (SEE COMMENT). (B-DLCL-NC)

Diagnosis Comment:

The lymphoma is immunophenotypically consistent with non-GCB type.

ICD-O3

lymphoma, diffuse,
large B-cell, NOS
968013

Signed:

Site: lymph node, cervical

C77.0 9-2012 RD

Flow Cytometry

Date Ordered: [Redacted]
Date Reported: [Redacted]

Status: [Redacted]

Interpretation

Lymph Node Left Neck: A population of mature B-cells with increased forward and side light scatter expressing CD19, CD20, partial CD25, high-density CD38 and monotypic, intermediate density lambda light chains is present at 43% of lymphocytes (25% of isolated cells). This phenotype is consistent with a B-cell lymphoproliferative disorder and suggests an intermediate to high-grade process. Correlation with morphologic studies is required for definitive classification.

** Note: For additional testing details see Flow Cytometry Report.

These materials were examined by all persons listed on this report.

able staff pathologist

[page 2 of 6]
Name: [REDACTED]
Submitted by: [REDACTED]

D.O.B. [REDACTED]
Date Taken [REDACTED]

Sex: F

Accession No: [REDACTED]
Hosp No: [REDACTED]

Surgical Pathology

History:

The patient is a [REDACTED]-year-old female with atypical lymphocytes noted on fine needle aspiration of neck mass, and common variable immunodeficiency.

Source/Gross:

Received fresh in a container labeled "[REDACTED]" and designated "left lymph neck node for lymphoma studies" is a tan-pink lymph node candidate (2.2 x 2.1 x 1.3 cm). The lymph node candidate is triaged for Lymphoma Study Protocol after consultation with Dr.

Lymphoma Study protocol:

- 1 piece for flow cytometry
- 2 touch imprints
- 1 piece for cytogenetic studies
- 1 piece frozen in OCT for immunohistochemistry
- 1 piece frozen in foil for molecular biology
- A1 B-plus fixation
- A2-5 24-hour formalin fixation
- [REDACTED]
- [REDACTED]

[page 3 of 6]
Name: [REDACTED] D.O.B. [REDACTED] Sex: F Accession No: [REDACTED]
Submitted by: [REDACTED] Date Taken: [REDACTED] Hosp No: [REDACTED]

Surgical Pathology

Microscopic:

IMMUNOPEROXIDASE REPORT

PARAFFIN TISSUE - (Done at [REDACTED])

B-Cell Markers

T-Cell Markers

Other Markers

CD20(L26)	+ ✓	CD45RO(UCHL1)	ND	CD45(LCA)	ND
CD79a	ND	CD43(L60)	ND	CD30(Ber-H2)	ND
CD10	- ✓	CD3	- ✓	CD15(Leu M1)	ND
		CD5	- ✓	BCL-2	- ✓
				BCL-6	+ ✓
				EBERs	- ✓
				MUM1	+ ✓

INTERPRETATION: The paraffin markers indicate a B-cell phenotype, consistent with non-GCB subtype.

RNA control for in situ is acceptable. The BIV study was developed and its performance characteristics determined by The [REDACTED] Immunoperoxidase Laboratory. It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments (CLIA) as qualified to perform high complexity clinical laboratory testing.

Participating Fellow: [REDACTED]

[page 4 of 6]
Department of Pathology and Microbiology

Name: [REDACTED] Accession No: [REDACTED]
Hosp No: [REDACTED] Acct No: [REDACTED] Date Taken: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] Date Received: [REDACTED]
Sex: [REDACTED] SSN: [REDACTED] Submitted by: [REDACTED]
Loc: [REDACTED] Room: [REDACTED] Client: [REDACTED]

Flow Cytometry

Interpretation

Lymph Node Left Neck: A population of mature B-cells with increased forward and side light scatter expressing CD19, CD20, partial CD25, high-density CD38 and monotypic, intermediate density lambda light chains is present at 43% of lymphocytes (25% of isolated cells). This phenotype is consistent with a B-cell lymphoproliferative disorder and suggests an intermediate to high-grade process. Correlation with morphologic studies is required for definitive classification.

Signed: [REDACTED]

Procedure Notes:

CLINICAL HISTORY/ SUSPECTED DIAGNOSIS: Suspicious for lymphoma.

Specimen Source: Left Neck Lymph Node

Ficoll: No

Viability: 40%

% Abnormal cells: Monotypic B-cells at 43% of lymphocytes.

The specimen was analyzed using the following 23 antibodies:

CD45	+	CD10	-	CD11b	-
CD2	-	CD19	+	CD11c	-
CD3	-	CD20	+	CD14	-
CD4	-	CD23	-	CD16	-
CD5	-	CD24	-	CD25	+, partial

These materials were examined by all those listed to establish the diagnosis with the signature being the responsible staff pathologist

[page 5 of 6]
Name: [REDACTED] D.O.B. [REDACTED] Sex: F Accession No: [REDACTED]
Submitted by: [REDACTED] Date Taken: [REDACTED] Hosp No: [REDACTED]

Flow Cytometry

CD7	-	Kappa	-	CD34	-
CD8	-	Lambda	+, intermediate	CD38	+, bright
				CD56	-
				CD103	-

Clinical diagnosis and/or therapy should not be based solely on this assay. The results should be considered in conjunction with clinical information, morphologic findings, and additional diagnostic tests. This test was developed and its performance characteristics determined by the [REDACTED] Flow Cytometry Laboratory. It has not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments (CLIA) as qualified to perform high complexity clinical laboratory testing.

[REDACTED]

[page 6 of 6]
SURGICAL PATHOLOGY SPECIMEN REQUEST FORM

PATIENT INFORMATION

NAME

MR

MTC

DATE

SEX: ☐ Male ☒ Female

(AFFIX PATIENT LABEL HERE IF AVAILABLE)

CLINICAL HISTORY, PRE OPERATIVE DIAGNOSIS, POST OPERATIVE DIAGNOSIS, OR OTHER PERTINENT LABORATORY FINDINGS:

9-11-2012 FRI 10:40 AM

Excision left Lymph node biopsy

SPECIAL REQUEST: (Please specify)

ORDERING PROVIDER

FROZEN SECTION:

YES ☐NO ☒

REFERRING PHYSICIAN:

R NO.

EXT.

DATE/TIME SPECIMEN COLLECTION

FROZEN SECTION DIAGNOSIS:

SPECIMEN SOURCE:

- Left neck lymph node biopsy
- Polymorphous glands - routine
- _____
- _____
- _____
- _____
- _____
- _____
- _____

PATHOLOGIST SIGNATURE: _____

REPORT TO: _____

TIME RECEIVED: _____

TIME REPORTED: _____

CREW CHECKLIST

- ☒ Patient's ID Check
- ☒ Site Verification
- ☒ Label Verification
- ☒ Form Complete
- ☒ Specimen and Form Bagged

Nursing Signature

LAB USE ONLY

NOT TO BE FILED IN PERMANENT MEDICAL RECORD
SURGICAL PATHOLOGY SPECIMEN REQUEST

Source: NCI Genomic Data Commons file bcc2c9aa-044e-47f5-82d3-a336ea9f2195 (TCGA-GR-A4D9.F4DE97A1-D58D-431F-8C93-8F0647F2F493.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).